Gene-level copy-number profile of tumor specimen TCGA-XF-A9SP-01A from TCGA case TCGA-XF-A9SP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 59.6 years (21,776 days).
Specimen TCGA-XF-A9SP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.1cc38573-3d67-46d8-bae6-9aed4180eaab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c135dac4-692a-4139-baf3-3d82e90ede60

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 801; copy number 2: 2,272; copy number 3: 4,940; copy number 4: 14,476; copy number 5: 14,295; copy number 6: 11,806; copy number 7: 2,604; copy number 8: 4,464; copy number 9: 2,055; copy number 10: 742; copy number 11: 155; copy number 12: 159; copy number 13: 121; copy number 14: 574; copy number 15: 60; copy number 16: 43; copy number 17: 6; copy number 18: 97; copy number 19: 55; copy number 22: 22; copy number 24: 8; copy number 32: 35; copy number 35: 3; copy number 46: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SP-01A-11D-A390-01): tumor purity 0.26, ploidy 5.27, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,125 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:73,073,382–75,728,123, 106 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr2:159,615,296–161,428,774, 29 genes, copy number 32: AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1, ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785, AC096656.1, RN7SL423P, AC009313.1, TANK-AS1, TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2.
- chr2:161,433,874–161,625,752, 6 genes, copy number 32: AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46.
- chr2:171,922,448–173,706,148, 30 genes, copy number 24–46: HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2.
- chr5:1,931,064–2,119,926, 1 gene, copy number 9 (within-gene range 7–9): AC124852.1.
- chr5:2,184,710–4,041,764, 17 genes, copy number 9: Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1.
- chr5:34,651,457–34,651,888, 1 gene, copy number 13: AC025754.2.
- chr5:34,656,412–34,657,250, 1 gene, copy number 13: AC025754.1.
- chr6:5,788,346–8,343,139, 52 genes, copy number 11–16: AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1.
- chr6:8,341,937–8,435,561, 2 genes, copy number 11: AL359378.1, SLC35B3.
- chr7:51,471,717–64,266,931, 263 genes, copy number 10–14 (within-gene range 8–14) (broad region; genes not listed).
- chr7:85,381,118–88,306,894, 29 genes, copy number 13–35: DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4.
- chr7:88,749,470–91,210,590, 23 genes, copy number 14 (within-gene range 8–14): AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1.
- chr7:95,772,506–103,514,007, 267 genes, copy number 9–18 (within-gene range 8–18) (broad region; genes not listed).
- chr7:103,484,208–103,484,539, 1 gene, copy number 18: RN7SKP86.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9–17 (broad region; genes not listed).
- chr9:14,475–1,550,103, 31 genes, copy number 9: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1.
- chr9:21,409,117–26,796,304, 55 genes, copy number 9: IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1.
- chr10:44,712–38,783,108, 675 genes, copy number 13–15 (broad region; genes not listed).
- chr12:111,443,485–112,898,881, 36 genes, copy number 9 (within-gene range 4–9): ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1.
- chr13:88,472,151–91,354,579, 36 genes, copy number 9: AL355677.1, LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:101,452,593–101,720,856, 1 gene, copy number 9 (within-gene range 6–9): ITGBL1.
- chr13:101,717,564–101,967,746, 4 genes, copy number 9: AL160153.1, RNU1-24P, HMGB3P7, MIR2681.
- chr15:19,878,555–24,090,821, 177 genes, copy number 9 (broad region; genes not listed).
- chr15:24,162,754–24,343,464, 4 genes, copy number 9: PWRN2, AC087463.1, AC087463.2, AC087463.3.
- chr17:1,344,275–2,381,058, 55 genes, copy number 19 (within-gene range 6–19): YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1, RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1, SMG6, AC090617.9, AC090617.4, AC090617.6, AC090617.8, AC090617.7, MCUR1P1, RN7SL624P, AC090617.2, AC090617.1, AL450226.1, SMG6-IT1, AL450226.2, SRR, HNRNPA1P16, TSR1, SNORD91B, SNORD91A, SGSM2.
- chr18:47,390–15,330,282, 376 genes, copy number 10 (broad region; genes not listed).
- chr19:27,638,483–29,093,031, 35 genes, copy number 11: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1.
- chr19:52,838,010–55,836,800, 278 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 795. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
